TCGA case TCGA-P5-A5ET — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d87742fd-ff94-4ef0-bbf4-5dd5a185a0e7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 27 years; Vital status: Alive.

Diagnoses (1)
1. Oligodendroglioma, NOS: ICD-O-3 morphology code: 9450/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 27.5 years (10,027 days); Year of diagnosis: 2012; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 0 days; First symptom longest duration: 91-180 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Frontal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day -10.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-P5-A5ET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 400 mg.
  Slide TCGA-P5-A5ET-01A-01-TSA: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 80; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
- Sample TCGA-P5-A5ET-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; History ionizing radiation to head: No; Tumor status: Tumor free; Tumor site: Supratentorial, Frontal Lobe; Supratentorial localization: Not listed in Medical Record; History headaches: Yes; First symptom longest duration: 91 - 180 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant medication: Yes; Idh1 mutation test indicator: No; Inherited genetic syndrome indicator: No; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 0 days; disease-specific survival: no event (censored), 0 days; progression-free interval: no event (censored), 0 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-P5-A5ET-01A-11D-A27J-01): tumor purity 0.84, ploidy 1.95, whole-genome doublings 0.
